TCGA case TCGA-QT-A5XJ — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59f305d2-dca8-4ec7-8708-27b4b105fc72

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (6)
1. Pheochromocytoma, malignant (the primary disease): ICD-O-3 morphology code: 8700/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 42.5 years (15,535 days); Year of diagnosis: 2011; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,102 days (3.0 years); Cancer detection method: Screening.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 13; Lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Temozolomide; Days to treatment start: 113 days; Days to treatment end: 326 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Connective, subcutaneous and other soft tissues of thorax. Age at diagnosis: 42.7 years (15,612 days); Days to diagnosis: 77 days; Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Lymph node, NOS. Age at diagnosis: 42.8 years (15,628 days); Days to diagnosis: 93 days; Prior treatment: Yes.
4. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Bone, NOS. Age at diagnosis: 43.2 years (15,762 days); Days to diagnosis: 227 days; Prior treatment: Yes.
5. Subsequent primary of the breast (histology not recorded by GDC). Age at diagnosis: 43.9 years (16,036 days); Days to diagnosis: 501 days (1.4 years); Prior treatment: Yes.
6. Metastasis of diagnosis 1 (Pheochromocytoma, malignant), site: Breast, NOS. Age at diagnosis: 45.4 years (16,579 days); Days to diagnosis: 1,044 days (2.9 years); Prior treatment: Yes.

Follow-up (8 entries)
- Day 0 (prior to diagnosis): History of tumor: No; History of tumor type: Phenochromocytoma or Paraganglioma.
- Day 77 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of thorax; Days to progression: 77 days; Evidence of progression type: Histologic Confirmation.
- Day 93 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 93 days; Evidence of progression type: Convincing Image Source.
- Day 93 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 93 days; Evidence of recurrence type: Convincing Image Source.
- Day 227 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 227 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 773 days (2.1 years); Disease response: With Tumor.
- Day 1,044 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Breast, NOS; Days to progression: 1,044 days (2.9 years); Evidence of progression type: Histologic Confirmation.
- Days to follow up: 1,102 days (3.0 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QT-A5XJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 490 mg.
  Slide TCGA-QT-A5XJ-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QT-A5XJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QT-A5XJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History pheo or para include benign: No; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Pheochromocytoma; Disease detected on screening: Yes; Ct scan preop results: Yes; Lymph nodes examined: Yes.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 1: Pharmaceutical therapy drug name: Xeloda; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,102 days; disease-specific survival: no event (censored), 1,102 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 77 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QT-A5XJ-01A-11D-A35C-01): tumor purity 0.91, ploidy 1.83, whole-genome doublings 0.
